Somatic mutation profile of tumor specimen TCGA-QT-A69Q-01A (aliquot TCGA-QT-A69Q-01A-11D-A35D-08) from TCGA case TCGA-QT-A69Q, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Medulla of adrenal gland; Age at diagnosis: 40.7 years (14,866 days).
Specimen TCGA-QT-A69Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75200154-7202-45f2-a030-54bcd8ddc5bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QT-A69Q-10A (Blood Derived Normal), aliquot TCGA-QT-A69Q-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1303ea73-2918-4545-92f9-e227b5a04bab

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDC42BPA | c.415A>G p.T139A | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as rs146827361; called by muse, mutect2, varscan2
- F13A1 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs138865075; called by muse, mutect2, varscan2
- NID2 | c.2138C>T p.P713L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.568); catalogued as rs758339983; called by muse, mutect2, varscan2
- SETD1A | c.3355G>T p.A1119S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as rs763821551; called by mutect2, varscan2
- SPDYE1 | c.235_237del p.H79del | In Frame Del (DEL) | VAF 7/52 reads (13%) | catalogued as rs755134757; called by pindel, varscan2
- DCK | c.34T>G p.F12V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXOC2 | c.914A>G p.D305G | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RPAP1 | c.2704A>T p.N902Y | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); called by muse, mutect2
- TIAM2 | c.3661G>C p.D1221H | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHNAK | c.14160G>A p.K4720= | Silent (SNP) | VAF 36/275 reads (13%) | called by muse, mutect2, varscan2
- CDHR5 | c.1827C>T p.P609= (on ENST00000358353 / NM_001171968.2; = p.P615= on NM_021924.5) | Silent (SNP) | VAF 9/132 reads (7%) | catalogued as rs554478114, COSV57643260; called by muse, mutect2
- NUMBL | c.523C>T p.L175= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as rs750033806; called by muse, mutect2
